Gene-level copy-number profile of tumor specimen TCGA-TM-A84J-01A from TCGA case TCGA-TM-A84J, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 63.2 years (23,091 days).
Specimen TCGA-TM-A84J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.efa0ff92-369a-4408-8cab-9f5b013e1cf1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TM-A84J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e1afd98-8bde-4d09-a38d-78d7f4fd6c25

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,496; copy number 3: 6,593; copy number 4: 46,482; copy number 5: 3,206; copy number 6: 561; copy number 7: 229; copy number 14: 9; copy number 15: 3; copy number 22: 44; copy number 23: 4; copy number 24: 28; copy number 25: 28; copy number 26: 55; copy number 27: 4; copy number 28: 5; copy number 29: 3; copy number 30: 6; copy number 31: 16; copy number 32: 2; copy number 35: 26; copy number 41: 1; copy number 43: 2; copy number 45: 8; copy number 47: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TM-A84J-01A-11D-A36N-01): tumor purity 0.91, ploidy 3.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 245 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,266,239–23,302,866, 28 genes, copy number 25: MIR4418, PPIAP34, AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253, LACTBL1, TEX46, KDM1A, AL031428.1, MIR3115, AL031428.2, LUZP1, AL161672.1, RNU6-514P, RNU6-135P, HTR1D, AL109936.1, LINC01355, AL109936.9.
- chr1:156,082,573–157,138,474, 55 genes, copy number 26 (within-gene range 5–26): LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1, MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE, GPATCH4, AL365181.4, HAPLN2, AL365181.2, BCAN, AL365181.3, AL590666.2, NES, AL590666.3, AL590666.4, CRABP2, AL590666.1, ISG20L2, RRNAD1, MRPL24, HDGF, PRCC, AL590666.5, SH2D2A, NTRK1, INSRR, PEAR1, LRRC71, ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45, ETV3L, ETV3, CYCSP52.
- chr10:11,920,022–12,196,144, 7 genes, copy number 31: UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5.
- chr10:22,162,992–22,232,973, 6 genes, copy number 24: ADIPOR1P1, AL157831.1, EBLN1, AL157831.2, PSME2P6, AL157831.3.
- chr10:22,439,954–22,479,480, 1 gene, copy number 30: AL513128.3.
- chr10:43,556,344–43,596,625, 2 genes, copy number 43 (within-gene range 3–43): ZNF239, AL450326.3.
- chr10:100,273,280–100,519,864, 8 genes, copy number 45 (within-gene range 3–45): BLOC1S2, PKD2L1, AL139819.1, SCD, OLMALINC, Y_RNA, WNT8B, SEC31B.
- chr10:116,671,192–116,850,251, 2 genes, copy number 32 (within-gene range 3–32): HSPA12A, RPL5P27.
- chr11:121,361,854–122,619,274, 20 genes, copy number 24: BMPR1AP2, AP002365.1, AP000977.1, SORL1, AP001977.1, AP001924.1, RNU6-256P, AP001924.2, MIR100HG, MIR125B1, BLID, MIRLET7A2, MIR100, AP000755.1, AP000755.2, RNU4ATAC10P, RNU4ATAC5P, RNU6-592P, GLULP3, AP002469.1.
- chr22:18,970,439–19,291,719, 26 genes, copy number 35 (within-gene range 7–35): DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1, DGCR2, Y_RNA, DGCR11, AC004461.1, AC004461.2, AC004471.1, AC004471.2, TSSK1A, ESS2, TSSK2, GSC2, LINC01311, SLC25A1, CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62.
- chr22:19,479,457–19,520,612, 1 gene, copy number 28: CDC45.
- chr22:20,917,407–21,081,018, 19 genes, copy number 22: CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4.
- chr22:23,433,564–23,486,980, 3 genes, copy number 29: LINC01659, AP000344.1, FAM230I.
- chr22:27,276,240–27,286,349, 1 gene, copy number 41 (within-gene range 6–41): AL020994.3.
- chr22:30,475,364–30,505,711, 3 genes, copy number 30: AC004832.1, SDC4P, SEC14L4.
- chr22:31,618,491–31,956,243, 9 genes, copy number 31 (within-gene range 6–31): PISD, MIR7109, PRR14L, DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1.
- chr22:32,413,847–32,464,484, 1 gene, copy number 15: BPIFC.
- chr22:32,507,820–33,058,381, 1 gene, copy number 28 (within-gene range 5–28): SYN3.
- chr22:32,783,177–33,015,461, 3 genes, copy number 28: Z73495.1, TIMP3, Z83846.1.
- chr22:35,249,772–35,347,992, 4 genes, copy number 27 (within-gene range 7–27): RNU7-167P, HMGXB4, AL008635.1, TOM1.
- chr22:38,861,422–38,992,778, 4 genes, copy number 23: CBX6, AL022318.5, AL022318.1, APOBEC3A.
- chr22:39,223,359–39,437,060, 10 genes, copy number 22 (within-gene range 5–22): PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1.
- chr22:41,447,830–41,529,273, 1 gene, copy number 22 (within-gene range 6–22): ACO2.
- chr22:41,525,799–41,589,871, 4 genes, copy number 22: POLR3H, AL023553.1, CSDC2, PMM1.
- chr22:43,197,280–43,343,372, 1 gene, copy number 15 (within-gene range 6–15): SCUBE1.
- chr22:43,275,955–43,283,830, 1 gene, copy number 15: SCUBE1-AS1.
- chr22:45,344,063–45,413,619, 1 gene, copy number 47 (within-gene range 5–47): SMC1B.
- chr22:45,671,798–46,044,853, 9 genes, copy number 14 (within-gene range 6–14): ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899.
- chr22:46,576,012–46,738,252, 2 genes, copy number 24 (within-gene range 5–24): GRAMD4, CERK.
- chr22:49,213,911–49,266,080, 2 genes, copy number 30: RPL35P8, Z82202.1.
- chr22:50,669,804–50,801,309, 10 genes, copy number 22: Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
